Somatic mutation profile of tumor specimen TCGA-NA-A4R1-01A (aliquot TCGA-NA-A4R1-01A-11D-A28R-08) from TCGA case TCGA-NA-A4R1, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC1; Age at diagnosis: 75.8 years (27,688 days).
Specimen TCGA-NA-A4R1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04dec5c5-2ace-4820-ab09-675f3b3e9370.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NA-A4R1-10A (Blood Derived Normal), aliquot TCGA-NA-A4R1-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75c3cd49-668e-48c5-bd03-eaa9059a6d56

The open-access MAF lists 131 somatic variants for this specimen: 94 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 34, Frame Shift Del 13, Frame Shift Ins 9, Nonsense Mutation 7, Intron 3, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 43/45 reads (96%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 24/26 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.11255G>T p.C3752F | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs750247618; called by muse, mutect2, varscan2
- ANKIB1 | c.437dup p.N146Kfs*29 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs201434379; called by mutect2, varscan2
- APAF1 | c.697C>T p.R233C (on ENST00000551964 / NM_181861.2; = p.R222C on NM_001160.3) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs768971192; called by muse, mutect2, varscan2
- BAZ1B | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs376917030; called by muse, mutect2, varscan2
- BCAT2 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751932058, COSV60272159; called by muse, mutect2, varscan2
- CLIC4 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV65525313; called by muse, mutect2, varscan2
- COPB1 | c.2602C>T p.H868Y | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as rs1323869609; called by muse, mutect2, varscan2
- CREBBP | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as rs759312345, COSV52115896; called by muse, mutect2, varscan2
- CRYBG2 | c.3181G>A p.G1061S | Missense Mutation (SNP) | VAF 113/235 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746670731; called by muse, mutect2, varscan2
- CTNND2 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs757809631, COSV58866465; called by muse, mutect2, varscan2
- F8 | c.5012G>A p.R1671H | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs782166477, CM082643, COSV64270712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCC | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs370346767, CM128673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCGBP | c.8902G>A p.V2968M | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs779223629; called by muse, mutect2
- FGB | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.377); catalogued as rs121909620, CM920275; ClinVar: other; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.845del p.F282Sfs*15 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs751624085; called by mutect2, varscan2
- GNB1 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as rs1024722484, COSV66099799; called by muse, mutect2, varscan2
- HELZ | c.2789G>A p.R930H | Missense Mutation (SNP) | VAF 52/54 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1216248582; called by muse, mutect2, varscan2
- IFNLR1 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 102/202 reads (50%) | catalogued as COSV59525928; called by muse, mutect2, varscan2
- INSRR | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748927042, COSV63871763; called by muse, mutect2, varscan2
- KNDC1 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1183395152; called by muse, mutect2, varscan2
- LPP | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 51/53 reads (96%) | catalogued as rs1399332919; called by muse, mutect2, varscan2
- LRRC7 | c.127C>T p.R43W (on ENST00000651989 / NM_001370785.2; = p.R10W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150507629; called by muse, mutect2, varscan2
- LTK | c.2453dup p.Q819Tfs*16 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | catalogued as rs1380788604; called by mutect2, pindel, varscan2
- MALSU1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs767582615; called by muse, mutect2, varscan2
- MED12 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61348876; called by muse, mutect2, varscan2
- METTL14 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as rs1233670392; called by muse, mutect2, varscan2
- MUC2 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765192322; called by muse, mutect2, varscan2
- MYBPC2 | c.2926del p.T976Pfs*76 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs757263482; called by mutect2, pindel, varscan2
- MYH7 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759579652, CM1412221, COSV100806354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCF2 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs890662812, COSV100838875; called by muse, mutect2, varscan2
- NYNRIN | c.4970C>T p.T1657M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201409522; called by muse, mutect2, varscan2
- PCDHGB1 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV99529035; called by muse, mutect2, varscan2
- PDE1B | c.1565dup p.S523Ifs*6 | Frame Shift Ins (INS) | VAF 38/100 reads (38%) | catalogued as rs780236743; called by mutect2, varscan2
- PRKD2 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as rs775746699; called by muse, mutect2, varscan2
- PRPF8 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 104/109 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs760462310; called by muse, mutect2, varscan2
- PTPN18 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs11892325; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | catalogued as rs772722517, COSV99560265; called by mutect2, pindel, varscan2
- RANBP6 | c.2918del p.N973Mfs*12 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs746880803; called by mutect2, varscan2
- RASSF5 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 141/231 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs782638829; called by muse, mutect2, varscan2
- SH3BP4 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1172262615; called by muse, mutect2, varscan2
- SLC25A27 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 33/68 reads (49%) | catalogued as rs772948449, COSV51495334, COSV51497762; called by muse, mutect2, varscan2
- SPTB | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.46); catalogued as rs779669473, COSV67629838; called by muse, mutect2
- TENT4A | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766747987, COSV50098074; called by muse, mutect2, varscan2
- TMEM94 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV58598836, COSV58600101; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs756650873; called by mutect2, varscan2
- TYMS | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 37/74 reads (50%) | catalogued as COSV51893570; called by muse, mutect2, varscan2
- USP31 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs776961232, COSV54850208; called by muse, mutect2, varscan2
- ZEB1 | c.2917G>A p.G973R | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1324134113, COSV58051584; called by muse, mutect2, varscan2
- ZNF449 | c.830dup p.E278Rfs*23 | Frame Shift Ins (INS) | VAF 48/104 reads (46%) | catalogued as rs781874073; called by mutect2, varscan2
- ZNF574 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1439847235; called by muse, mutect2, varscan2
- ACIN1 | c.3352C>T p.H1118Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ADAM9 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AIP | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- AKAP9 | c.8869G>A p.E2957K (on ENST00000359028; = p.E2933K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- AMOT | c.1784del p.K595Rfs*29 (on ENST00000371959 / NM_001113490.1; = p.K186Rfs*29 on NM_133265.3) | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- ARHGAP12 | c.418dup p.Y140Lfs*2 | Frame Shift Ins (INS) | VAF 49/70 reads (70%) | called by mutect2, pindel, varscan2
- ATL3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); called by muse, mutect2
- ATP5PD | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 132/218 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, varscan2
- BNC2 | c.3113A>G p.N1038S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- C5orf15 | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CD14 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CDH26 | c.2389A>G p.S797G (on ENST00000348616 / NM_177980.4; = p.S130G on NM_021810.6) | Missense Mutation (SNP) | VAF 68/106 reads (64%) | SIFT tolerated (0.73); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CDHR5 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CHD1 | c.4970A>G p.D1657G | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DLEC1 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DLST | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC14 | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FPR3 | c.270del p.K90Nfs*11 | Frame Shift Del (DEL) | VAF 53/282 reads (19%) | called by mutect2, pindel, varscan2
- GJB3 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 73/132 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KALRN | c.3151dup p.L1051Pfs*14 | Frame Shift Ins (INS) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- KLC1 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- LATS2 | c.1772_1773del p.E591Vfs*12 | Frame Shift Del (DEL) | VAF 79/210 reads (38%) | called by pindel, varscan2
- LHCGR | c.774del p.K258Nfs*16 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- MANEA | c.831del p.K277Nfs*6 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel, varscan2
- MYO7A | c.1721A>G p.H574R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- NIPBL | c.4269dup p.V1424Cfs*6 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- NRXN1 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NSD1 | c.6809C>A p.A2270E | Missense Mutation (SNP) | VAF 109/229 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2
- PCDHB5 | c.234T>A p.D78E | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PFKL | c.732_733dup p.E245Vfs*14 | Frame Shift Ins (INS) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- RASEF | c.1508A>G p.Q503R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC20A2 | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SULT1B1 | c.129del p.I43Mfs*16 | Frame Shift Del (DEL) | VAF 54/123 reads (44%) | called by mutect2, pindel, varscan2
- TADA1 | c.608A>G p.H203R | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMF1 | c.1348-2A>G p.X450_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | called by muse, varscan2
- TULP4 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- USP15 | c.2349del p.K783Nfs*4 (on ENST00000280377 / NM_001351159.2; = p.K754Nfs*4 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/17 reads (76%) | called by mutect2, pindel, varscan2
- UTP25 | c.1322C>A p.P441Q | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- YY2 | c.1109dup p.N370Kfs*24 | Frame Shift Ins (INS) | VAF 104/288 reads (36%) | called by mutect2, pindel, varscan2
- ZBTB1 | c.1571del p.K524Sfs*25 | Frame Shift Del (DEL) | VAF 28/149 reads (19%) | called by mutect2, pindel, varscan2
- ZNF71 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF804B | c.962A>G p.H321R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- AKAP13 | c.5652C>T p.T1884= (on ENST00000394518 / NM_007200.5; = p.T1888= on NM_006738.6) | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs1391572905; called by muse, mutect2, varscan2
- ALPK2 | c.120G>A p.K40= | Silent (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- BRINP3 | c.1474C>T p.L492= | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as COSV66531368; called by muse, mutect2, varscan2
- CHRNA4 | c.807C>T p.S269= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs201335931, COSV64718687; called by muse, mutect2, varscan2
- CYP1B1 | c.639C>T p.R213= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- DIS3 | c.1485C>T p.L495= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs774554288; called by muse, mutect2, varscan2
- DSC2 | c.1971C>T p.G657= | Silent (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- DYNAP | c.621C>T p.T207= (on ENST00000321600; = p.T181= on NM_173629.3) | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs373983597; called by muse, mutect2, varscan2
- EPHA8 | c.2907C>T p.D969= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1433765513, COSV51267681; called by muse, mutect2, varscan2
- ERMP1 | c.2631T>C p.P877= | Silent (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- FAT1 | c.13629C>T p.T4543= | Silent (SNP) | VAF 15/16 reads (94%) | catalogued as rs1240949530; called by muse, mutect2, varscan2
- FFAR1 | c.99C>T p.H33= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- HNF4A | c.519C>T p.N173= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs557888367; called by muse, mutect2, varscan2
- KYNU | c.681T>C p.T227= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs749842493; called by muse, mutect2, varscan2
- LRRC43 | c.630C>A p.P210= | Silent (SNP) | VAF 30/43 reads (70%) | called by muse, mutect2, varscan2
- MAGEA3 | c.786C>T p.P262= | Silent (SNP) | VAF 61/255 reads (24%) | catalogued as rs368605065; called by muse, mutect2, varscan2
- MAGI1 | c.3810A>G p.R1270= | Silent (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- NDNF | c.1359C>T p.I453= | Silent (SNP) | VAF 69/132 reads (52%) | catalogued as COSV65633441; called by muse, mutect2, varscan2
- NUDCD3 | c.54G>A p.Q18= | Silent (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- NUP205 | c.4134T>C p.P1378= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- PADI1 | c.1878C>T p.H626= | Silent (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4098G>A p.S1366= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as rs201994613, COSV62814247; called by muse, mutect2, varscan2
- PASK | c.717G>A p.S239= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs774944055; called by muse, mutect2, varscan2
- POLE | c.3912C>T p.P1304= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as rs116482376, COSV100266175, COSV57691640; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTBP2 | c.108G>A p.P36= (on ENST00000426398 / NM_001300986.2; = p.P28= on NM_021190.4) | Silent (SNP) | VAF 82/165 reads (50%) | catalogued as rs1449194049, COSV64623364; called by muse, mutect2, varscan2
- SIL1 | c.216G>A p.P72= | Silent (SNP) | VAF 86/140 reads (61%) | catalogued as rs750439304, COSV99498276; called by muse, mutect2
- SLC24A2 | c.849C>T p.N283= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs570505431; called by muse, mutect2, varscan2
- SRCIN1 | c.2871C>A p.T957= (on ENST00000621492; = p.T923= on NM_025248.3) | Silent (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- TEKT4 | c.297C>T p.H99= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs566487874; called by muse, mutect2
- TMEM201 | c.621C>T p.A207= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as rs201467842; called by muse, mutect2, varscan2
- UAP1L1 | c.498C>T p.Y166= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- WDHD1 | c.2463C>T p.A821= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs764452676; called by muse, mutect2, varscan2
- ZNF536 | c.3738G>A p.A1246= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as rs763122092, COSV62817654; called by muse, mutect2, varscan2
- ZNF83 | c.1356T>C p.T452= | Silent (SNP) | VAF 44/269 reads (16%) | called by muse, mutect2, varscan2
- HTR3E | c.68-79C>T | Intron (SNP) | VAF 50/112 reads (45%) | catalogued as rs142990158; called by muse, mutect2, varscan2
- OBSCN | c.18662-2757G>A | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- RMDN2 | c.452+22060A>G | Intron (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
